Gene-level copy-number profile of tumor specimen REBC-AC9L-TTM1-A from REBC case REBC-AC9L, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AC9L-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aceb0b59-501d-4f90-96c1-f2f30886d817.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AC9L-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/2bbd46b4-ff91-4af3-a73b-48ee852f7a2a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 133; copy number 2: 56,746; copy number 3: 1,515; copy number 5: 1; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 9: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.

Autosomal genes at a single copy (total copy number 1): 133. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
